TCGA case TCGA-WC-AA9A — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/01b18f83-da8a-4d3f-b722-f00fe7559c60

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Dead; Days to death: 453 days (1.2 years); Cause of death: Cancer Related.

Diagnoses (3)
1. Spindle cell melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8772/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 70.2 years (25,641 days); Year of diagnosis: 2011; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIA; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic stage: Stage IIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 453 days (1.2 years); Sites of involvement: Eye, Choroid.
   Pathology details: Consistent pathology review: Yes; Extrascleral extension present: No; Measurement type: Pathologic; Spindle cell percent range: >90%; Tumor depth measurement: 6.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 14.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the breast (histology not recorded by GDC). Laterality: Left.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -4,019 days (-11.0 years); Treatment anatomic sites: Breast.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Spindle cell melanoma, NOS), site: Skin, NOS. Age at diagnosis: 71.2 years (26,012 days); Days to diagnosis: 371 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 371 days (1.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (2 entries)
- Day 371 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin, NOS; Days to progression: 371 days (1.0 years).
- Days to follow up: 453 days (1.2 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 61.1 kg; Height: 158 cm; BMI: 24.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WC-AA9A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 30 mg.
  Slide TCGA-WC-AA9A-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WC-AA9A-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WC-AA9A-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Cause of death: Metastatic Uveal Melanoma.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Spindle Cell; Tumor morphology percentage: >90%.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness: 6 mm; Tumor thickness measurement: Pathologic Measurement.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast.
- Other malignancy form, Surgery: Other malignancy surgery type: left mastectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 453 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 453 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 371 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WC-AA9A-01A-11D-A39V-01): tumor purity 1, ploidy 1.92, whole-genome doublings 0.
